Surgical pathology report (de-identified scan), TCGA case TCGA-VP-AA1N, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-AA1N-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

DOB:

Surgical Pathology Report

Final

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 6/13/14

Patient Name:

Address:

Gender:

M

DOB:

Service:

Location:

MRN:

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned

Reported:

Physician(s):

DIAGNOSIS:

PROSTATE, RADICAL PROSTATECTOMY:

- ADENOCARCINOMA, GLEASON GRADE 5 + 4 = SCORE OF 9 (SEE SYNOPSIS)
- 30% OF THE PROSTATE GLAND IS INVOLVED BY CARCINOMA
- CARCINOMA INVOLVES LEFT APEX, RIGHT APEX, AND LEFT BASE
- RIGHT BASE IS FREE OF TUMOR
- EXTRAPROSTATIC EXTENSION IDENTIFIED AT LEFT APEX AND LEFT BASE, AND INTO BLADDER NECK (SEE COMMENT)
- CARCINOMA FOCALLY EXTENDS TO RIGHT DISTAL APICAL RESECTION MARGIN; ALL OTHER MARGINS, INCLUDING BLADDER NECK AND PERIPHERAL MARGINS ARE FREE OF TUMOR

SEMINAL VESICLES, BILATERAL, RADICAL PROSTATECTOMY

- NO EVIDENCE OF MALIGNANCY

LYMPH NODES, BILATERAL PELVIC, EXCISION:

- FIVE LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (0/5)

Intraoperative Consultation:

"Brought to frozen, 'prostate,' consisting of a 34.6 gram prostate (4 x 4 x 3.8 cm) with bilateral seminal vesicles. Tissue taken for tumor bank. Rest for permanents."

Microscopic Description and Comment:

Sections show adenocarcinoma of the prostate, Gleason grade 5 + 4 = score of 9, involving 30% of the prostate gland.

[page 2 of 3]
Patient Name: [REDACTED]

DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

as determined by a grid morphometric technique. There is established extraprostatic extension by carcinoma at the left apex and left base. There is also extension into bladder neck (slide B7), which is formally pT4 according to the 2002 TNM scheme, but follow-up data from several studies indicate that this bladder neck involvement is more appropriately designated pT3.

History:

The patient is a [REDACTED] with a history of prostate cancer. Operative procedure: Robotic assisted laparoscopic prostatectomy.

Specimen(s) Received:

A: LYMPH NODE, BILATERAL PELVIC
B: PROSTATE

Gross Description:

The specimens are received in two formalin-filled containers, each labeled [REDACTED]. The first container is labeled "bilateral pelvic lymph nodes." Five lymph nodes are identified. Labeled A1, one lymph node bisected; A2, four lymph nodes. Jar 1.

The second container is labeled "prostate." It holds the previously described, 34.6 gram prostate measuring 4 x 4 x 3.8 cm. The bilateral seminal vesicles are attached. The right seminal vesicle measures 2.9 cm in length. The left seminal vesicle measures 3 cm in length. The prostate has been previously inked blue. The prostatic urethra is probe patent. Labeled B1, bladder neck margin; B2, left apex margin; B3, right apex margin; B4 and B5, left apex; B6 and B7, left base; B8 and B9, right apex; B10 and B11, right base; B12, left seminal vesicle; B13, right seminal vesicle. Jar 1.

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The tumor type is adenocarcinoma, acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) = 30%, as determined by a grid morphometric technique

GLEASON'S GRADE

The Gleason's Grade is 5+4=9

[page 3 of 3]
Patient Name: [REDACTED]

DOB: [REDACTED]

SURGICAL PATHOLOGY REPORT

TUMOR LOCATION

The location of the tumor involves the
right apex
left base
left apex

PERINEURAL INVASION

Perineural invasion is identified

VASCULAR INVASION

Vascular invasion is not identified

EXTRAPROSTATIC EXTENSION

Extraprostatic (extracapsular) extension is established
The tumor extends into the periprostatic soft tissues (specify site): left base and left apex

SEMINAL VESICLES

Seminal vesicles are free of tumor

SAMPLED SPECIMEN MARGINS

Tumor is present at sampled distal apical (urethral) margin of resection
with 1 mm of involvement

NON-NEOPLASTIC PROSTATE

The non-neoplastic prostate shows PIN, high grade, focal

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

Bilateral pelvic: 0/5

PRIMARY TUMOR (T)

Extracapsular extension (unilateral or bilateral) (T3a)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis (N0)

DISTANT METASTASIS

No distant metastasis (M0)

STAGE GROUPING

Based on this information, the overall AJCC/UICC stage of the tumor is T3/N0/M0/Gleason score 5 + 4 = 9 (Stage III)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Surgical Pathology report is available

END OF REPORT

Page 3 of 3

Page: 3 of 3

Printed from

Source: NCI Genomic Data Commons file 9a62d39c-9c65-4354-a625-3ce65b3fab8c (TCGA-VP-AA1N.B76B30C1-F87D-494B-A95A-3F9E511ED3B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).